Gene-level copy-number profile of tumor specimen TCGA-13-1403-01A from TCGA case TCGA-13-1403, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.5 years (17,697 days).
Specimen TCGA-13-1403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.78a6bb48-90a5-4353-8a06-49c2975760a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1403-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a45a1a0b-8ff1-458b-b865-4ae19d0695b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 14,246; copy number 2: 35,827; copy number 3: 6,993; copy number 4: 1,531; copy number 5: 843; copy number 6: 80; copy number 7: 241.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1403-01A-01D-0452-01): tumor purity 0.93, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:96,816,269–97,601,743, 29 genes (within-gene range 0–1): ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV, TCEA1P1, GAS2L1P2, VN1R51P, FAM220CP, AL445670.1, ANKRD18CP, RNU6-798P, AL590705.3, ZNF322P1, AL590705.1, AL590705.2, SUGT1P4-STRA6LP, STRA6LP, SUGT1P4, AL512590.2, CCDC180, MIR1302-8, AL512590.1, AL512590.3, TDRD7, TMOD1, AL162385.1.
- chr17:31,272,013–31,637,543, 17 genes (within-gene range 0–2): OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3.
- chr22:49,805,452–49,838,901, 3 genes: Z98885.3, Z98885.1, Z98885.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,164 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,991,276–41,242,154, 80 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:233,614,106–248,919,946, 369 genes, copy number 5 (broad region; genes not listed).
- chr4:44,840,380–64,611,888, 241 genes, copy number 7 (broad region; genes not listed).
- chr8:120,535,745–145,066,685, 453 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:108,308,519–108,940,927, 7 genes, copy number 5 (within-gene range 3–5): C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29.
- chr12:33,576,095–34,249,958, 14 genes, copy number 5: RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.

Autosomal genes at a single copy (total copy number 1): 14,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
